Somatic mutation profile of tumor specimen TARGET-10-PASKTG-09A (aliquot TARGET-10-PASKTG-09A-01D) from TARGET case TARGET-10-PASKTG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,130 days).
Specimen TARGET-10-PASKTG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cafd80c-40a3-4303-ab7c-86d1eab64977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKTG-10A (Blood Derived Normal), aliquot TARGET-10-PASKTG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b78c80-dea1-4643-b235-7623c850c40a

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, In Frame Del 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP7 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs145686166; called by mutect2, varscan2
- CALM2 | c.213_215del p.M73del | In Frame Del (DEL) | VAF 19/40 reads (48%) | catalogued as COSV55399128; called by mutect2, pindel, varscan2
- DSP | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); catalogued as rs377652477; called by muse, mutect2, varscan2
- HPS1 | c.1793C>A p.T598N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57267249, COSV57269626; called by muse, mutect2, varscan2
- OIT3 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763468316, COSV61825463; called by muse, mutect2, varscan2
- LRP5 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDX1 | c.75G>A p.A25= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- SULT4A1 | c.717C>T p.N239= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs778676756; called by muse, mutect2, varscan2
- ADM2 | c.*361A>G | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895958 G>A | 5'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs754037240, COSV60001925; called by muse, mutect2, varscan2
